Somatic mutation profile of tumor specimen ALCH-AE7M-TTP1-A (aliquot ALCH-AE7M-TTP1-A-1-0-D-A587-36) from ALCHEMIST case ALCH-AE7M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.4 years (24,602 days).
Specimen ALCH-AE7M-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2e08967-cb7f-4e5e-895f-1fc8fe734b9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE7M-NB1-A (Blood Derived Normal), aliquot ALCH-AE7M-NB1-A-1-0-D-A587-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f328febc-74cf-41b8-8017-4c373629c687

The open-access MAF lists 571 somatic variants for this specimen: 397 protein-altering or splice-affecting, 110 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 339, Silent 110, Intron 29, Nonsense Mutation 20, Frame Shift Del 18, RNA 14, 3'UTR 11, Splice Site 8, 5'UTR 6, Frame Shift Ins 5, Splice Region 5, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 108/540 reads (20%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PNPLA6 | c.3548G>A p.R1183Q (on ENST00000414982 / NM_001166111.2; = p.R1135Q on NM_006702.5) | Missense Mutation (SNP) | VAF 103/459 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1057517802, COSV55385711; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV60632715; called by muse, mutect2, varscan2
- ACCS | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768714577, COSV55457061; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1905G>C p.L635F | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52822980; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3994C>A p.H1332N | Missense Mutation (SNP) | VAF 176/391 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs772013200; called by muse, mutect2, varscan2
- AMTN | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs1332859580; called by muse, mutect2, varscan2
- ANK2 | c.2273C>A p.T758N | Missense Mutation (SNP) | VAF 115/327 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100005128, COSV52151735; called by muse, varscan2
- ANKFN1 | c.1243C>A p.R415S | Missense Mutation (SNP) | VAF 157/448 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs370040478; called by muse, mutect2, varscan2
- APC2 | c.4145del p.P1382Rfs*198 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs1425656284; called by mutect2, pindel, varscan2
- ARID2 | c.4858C>A p.Q1620K | Missense Mutation (SNP) | VAF 114/347 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.037); catalogued as COSV57607968; called by muse, mutect2, varscan2
- ASL | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 48/336 reads (14%) | catalogued as rs944576125; called by muse, mutect2, varscan2
- ATP13A4 | c.1772A>T p.E591V | Missense Mutation (SNP) | VAF 111/562 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV99795394; called by muse, mutect2, varscan2
- BDKRB1 | c.1052G>A p.W351* | Nonsense Mutation (SNP) | VAF 94/156 reads (60%) | catalogued as COSV53705692; called by muse, mutect2, varscan2
- BRINP3 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 149/454 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100818418; called by muse, mutect2, varscan2
- C10orf120 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1306196935; called by muse, mutect2
- C19orf71 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs539296624; called by muse, mutect2
- C1QL2 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 68/398 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99733071; called by muse, varscan2
- C20orf194 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778174277; called by muse, mutect2, varscan2
- C6orf118 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); catalogued as COSV57812422; called by muse, mutect2, varscan2
- CBLN2 | c.562G>C p.V188L | Missense Mutation (SNP) | VAF 190/687 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54053231; called by muse, mutect2, varscan2
- CD8A | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.229); catalogued as COSV52156384, COSV52158909; called by muse, mutect2, varscan2
- CDH10 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 224/735 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as COSV52570760; called by muse, mutect2, varscan2
- CEP170 | c.2508A>T p.Q836H | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100317103; called by mutect2, varscan2
- CHTF18 | c.2561G>T p.R854L | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs375884550; called by mutect2, varscan2
- CIITA | c.3197G>T p.R1066L | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV60859939; called by muse, mutect2
- CNOT4 | c.821+1G>T p.X274_splice | Splice Site (SNP) | VAF 52/179 reads (29%) | catalogued as CS1212371, COSV59650961; called by muse, varscan2
- CNTNAP4 | c.2755G>T p.G919C | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100270346; called by muse, mutect2
- COA1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 163/614 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56241269; called by muse, mutect2, varscan2
- COL11A1 | c.3571C>A p.P1191T | Missense Mutation (SNP) | VAF 146/371 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV62181315; called by muse, mutect2, varscan2
- COL11A1 | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 165/430 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV62175815, COSV62200353; called by muse, mutect2, varscan2
- COL7A1 | c.3068C>T p.S1023F | Missense Mutation (SNP) | VAF 156/327 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs370335829; called by muse, mutect2, varscan2
- COPS5 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.384); catalogued as rs764699097; called by muse, mutect2, varscan2
- CSF2RA | c.615C>A p.F205L | Missense Mutation (SNP) | VAF 196/607 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs750757416, COSV62626327; called by muse, mutect2, varscan2
- CSMD1 | c.9049A>G p.T3017A (on ENST00000520002; = p.T3016A on NM_033225.6) | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs1000176854, COSV59383416; called by muse, mutect2, varscan2
- CTNNA3 | c.2272G>C p.D758H | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65523055; called by muse, mutect2, varscan2
- DGKE | c.1413-1G>A p.X471_splice | Splice Site (SNP) | VAF 39/299 reads (13%) | catalogued as COSV52348744; called by muse, mutect2, varscan2
- DIDO1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV99825730; called by muse, mutect2, varscan2
- DLC1 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 87/555 reads (16%) | catalogued as rs75294096; called by muse, mutect2, varscan2
- DLC1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 164/524 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV52324416; called by muse, mutect2, varscan2
- DLG2 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 148/361 reads (41%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as COSV101073189; called by muse, mutect2, varscan2
- DPY19L1 | c.1101+1G>T p.X367_splice | Splice Site (SNP) | VAF 41/151 reads (27%) | catalogued as COSV60581261; called by muse, mutect2, varscan2
- EFCAB2 | c.754G>A p.E252K (on ENST00000366522; = p.E116K on NM_032328.3) | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs778803377, COSV63658920; called by muse, mutect2, varscan2
- ENAM | c.3209C>A p.T1070N | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1446730438; called by muse, mutect2, varscan2
- EP300 | c.4307G>C p.W1436S | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54330637, COSV54343729; called by muse, mutect2, varscan2
- FAM171A1 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV65316261; called by muse, mutect2, varscan2
- FHL5 | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV100459758; called by muse, mutect2, varscan2
- FRMPD3 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1160103749, COSV52187939; called by muse, mutect2, varscan2
- FRY | c.5924G>A p.R1975Q | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs1377118027, COSV100969363; called by muse, mutect2, varscan2
- GMPS | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs748337752; called by muse, varscan2
- GPR132 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 70/101 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.204); catalogued as COSV61677731; called by muse, mutect2, varscan2
- HELZ2 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs745748912; called by muse, mutect2, varscan2
- HOXB6 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs1206013441, COSV53313790; called by muse, mutect2, varscan2
- HTR1B | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 105/346 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.142); catalogued as COSV100885363; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 125/1250 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs370073798; called by muse, mutect2
- IQSEC3 | c.1495G>A p.V499I (on ENST00000538872 / NM_001170738.2; = p.V196I on NM_015232.1) | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as COSV58285958; called by muse, mutect2, varscan2
- ITGA5 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99516907; called by muse, mutect2, varscan2
- JAKMIP3 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs747271149, COSV53824672; called by muse, mutect2, varscan2
- KCND2 | c.959G>T p.C320F | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1207633191; called by muse, mutect2, varscan2
- KCNG2 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1448905672; called by muse, mutect2, varscan2
- KCNU1 | c.1471G>T p.G491C | Missense Mutation (SNP) | VAF 79/493 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752389221; called by muse, mutect2, varscan2
- KEAP1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs1278385562, COSV50260974; called by muse, mutect2, varscan2
- KIR2DL1 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 162/282 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.61); catalogued as rs1304252990, COSV52413349; called by muse, mutect2, varscan2
- KIR3DL1 | c.554T>A p.M185K | Missense Mutation (SNP) | VAF 152/516 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs778270355; called by muse, mutect2, varscan2
- KLHL1 | c.852C>A p.N284K | Missense Mutation (SNP) | VAF 105/214 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.643); catalogued as rs1261688314; called by muse, mutect2, varscan2
- LDB3 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as rs1183240131; called by muse, varscan2
- LMO1 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 92/170 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373424725; called by muse, mutect2, varscan2
- LRRC37B | c.1852A>G p.I618V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV58953081; called by muse, mutect2, varscan2
- MAGEC1 | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.981); catalogued as COSV99594899; called by muse, mutect2, varscan2
- MAGEC1 | c.3119C>A p.P1040H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53579580; called by muse, mutect2, varscan2
- MGAM | c.3166G>T p.D1056Y | Missense Mutation (SNP) | VAF 92/307 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1219135693, COSV72075201; called by muse, mutect2, varscan2
- MLST8 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.552); catalogued as rs1201528887; called by muse, mutect2, varscan2
- MMS22L | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 90/293 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs141217754; called by muse, mutect2, varscan2
- MN1 | c.3132C>G p.F1044L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.117); catalogued as COSV56556159; called by muse, mutect2, varscan2
- MYH8 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 506/916 reads (55%) | catalogued as COSV67965711; called by muse, varscan2
- NCAM2 | c.979del p.E327Sfs*44 | Frame Shift Del (DEL) | VAF 84/366 reads (23%) | catalogued as COSV99521094; called by mutect2, pindel, varscan2
- NDST1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1478993046; called by muse, mutect2, varscan2
- NIBAN3 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1327778488; called by muse, mutect2, varscan2
- NLRP3 | c.2611G>T p.A871S | Missense Mutation (SNP) | VAF 174/722 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs201867582; called by muse, mutect2, varscan2
- NR0B1 | c.844C>G p.Q282E | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as CM088413; called by muse, mutect2, varscan2
- NRG1 | c.804G>T p.K268N (on ENST00000405005 / NM_013964.5; = p.K273N on NM_013956.5) | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV55156298; called by muse, mutect2, varscan2
- OLFM3 | c.734C>A p.P245H (on ENST00000338858 / NM_001288821.1; = p.P225H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/384 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557680935; called by muse, mutect2, varscan2
- OR10S1 | c.406C>A p.R136S | Missense Mutation (SNP) | VAF 141/333 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101602469; called by muse, mutect2, varscan2
- OR11L1 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 117/426 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63314269; called by muse, mutect2, varscan2
- OR14I1 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759549085; called by muse, mutect2, varscan2
- OR2T1 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs763683847, COSV63541298; called by muse, mutect2, varscan2
- OR2T3 | c.621C>G p.C207W | Missense Mutation (SNP) | VAF 83/389 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452493240, COSV62082480, COSV62083087; called by muse, mutect2, varscan2
- OR5D16 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 101/315 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758631072, COSV101003871; called by muse, mutect2, varscan2
- OR5J2 | c.888C>A p.D296E | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56620159; called by muse, mutect2
- OR5L1 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 142/498 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV61735211; called by muse, mutect2, varscan2
- OR5M11 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs761516023; called by muse, varscan2
- OR5M8 | c.786del p.S263Qfs*11 | Frame Shift Del (DEL) | VAF 36/244 reads (15%) | catalogued as rs760237003; called by mutect2, pindel, varscan2
- OR8U1 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 75/452 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV100164196; called by muse, mutect2, varscan2
- OVGP1 | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs370117565; called by muse, mutect2, varscan2
- PAPPA | c.4838C>A p.A1613D | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs537619729, COSV60284619; called by muse, mutect2, varscan2
- PAXIP1 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs767393974; called by muse, varscan2
- PCDHA10 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 223/540 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs781903292, COSV56537978; called by muse, mutect2, varscan2
- PCDHAC1 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs141300036, COSV53859699; called by muse, mutect2, varscan2
- PCDHGB2 | c.2315del p.P772Rfs*35 | Frame Shift Del (DEL) | VAF 153/494 reads (31%) | catalogued as COSV53984756; called by mutect2, pindel, varscan2
- PGAM1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373359947; called by muse, mutect2, varscan2
- PGR | c.1831G>T p.V611F | Missense Mutation (SNP) | VAF 198/513 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99677589; called by muse, mutect2, varscan2
- PLEKHG4B | c.541G>C p.D181H (on ENST00000283426; = p.D537H on NM_052909.5) | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs369489081; called by muse, mutect2, varscan2
- PLEKHS1 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 39/191 reads (20%) | catalogued as COSV63054386; called by muse, mutect2, varscan2
- POTEH | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 320/1530 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.925); catalogued as rs1355686873; called by muse, mutect2, varscan2
- POTEH | c.1475C>G p.P492R | Missense Mutation (SNP) | VAF 311/1507 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV58881726; called by muse, mutect2, varscan2
- PP2D1 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1394268683; called by muse, mutect2, varscan2
- PROKR2 | c.1098C>A p.D366E | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.174); catalogued as COSV54088682; called by muse, mutect2, varscan2
- PTPRC | c.2722G>T p.A908S | Missense Mutation (SNP) | VAF 163/553 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781540664; called by muse, mutect2, varscan2
- R3HCC1L | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs146287469; called by muse, mutect2, varscan2
- RAB3GAP1 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 146/550 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs771764402; called by muse, mutect2, varscan2
- RASGRF1 | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs552622510; called by muse, mutect2, varscan2
- RBMXL3 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.097); catalogued as rs1363399345; called by muse, mutect2, varscan2
- RBPJL | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs1023873396; called by muse, mutect2, varscan2
- REG1B | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 158/460 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59305024; called by mutect2, varscan2
- RIMS2 | c.2317C>A p.P773T (on ENST00000666250 / NM_001348490.2; = p.P581T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99167079; called by muse, mutect2, varscan2
- ROS1 | c.4550T>C p.I1517T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs770437430; called by muse, mutect2, varscan2
- RP1L1 | c.3653C>T p.A1218V | Missense Mutation (SNP) | VAF 71/367 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs1429388647, COSV66755562, COSV66759612; called by muse, mutect2, varscan2
- RYR3 | c.5357G>T p.G1786V | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV66808482; called by muse, mutect2, varscan2
- SALL4 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53849946; called by muse, mutect2, varscan2
- SCAF1 | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100862244; called by muse, mutect2, varscan2
- SCN1A | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 53/311 reads (17%) | catalogued as rs1553544680, COSV57670283; called by muse, mutect2, varscan2
- SCN9A | c.4895C>A p.T1632K (on ENST00000303354; = p.T1621K on NM_002977.3) | Missense Mutation (SNP) | VAF 131/360 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV57599078; called by muse, mutect2, varscan2
- SLC25A10 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs762740231, COSV100519158; called by muse, mutect2, varscan2
- SLC26A3 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 120/448 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs765288477, COSV60641616; called by muse, mutect2, varscan2
- SNX27 | c.1295G>C p.C432S | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV64327459; called by muse, mutect2, varscan2
- SOS1 | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 107/639 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67676665; called by muse, mutect2, varscan2
- SPTA1 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 86/629 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs186235809; called by muse, mutect2, varscan2
- ST18 | c.1689C>A p.Y563* | Nonsense Mutation (SNP) | VAF 195/597 reads (33%) | catalogued as COSV52508566; called by muse, mutect2, varscan2
- ST7 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 142/490 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.309); catalogued as rs754926097; called by muse, mutect2, varscan2
- STS | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 244/432 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1382685156; called by muse, varscan2
- TAGAP | c.1730C>A p.S577* | Nonsense Mutation (SNP) | VAF 86/267 reads (32%) | catalogued as COSV100487231; called by muse, mutect2, varscan2
- TGIF2LX | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 264/532 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV52213479; called by muse, varscan2
- TGIF2LX | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 242/467 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52213459, COSV99383345; called by muse, mutect2, varscan2
- TNR | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1052241944, COSV99689297; called by muse, mutect2, varscan2
- TP53 | c.410T>A p.L137Q | Missense Mutation (SNP) | VAF 216/339 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52661767, COSV53253629, COSV53721634; called by muse, mutect2, varscan2
- TRIM49 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 257/529 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.103); catalogued as COSV61671147; called by muse, mutect2, varscan2
- TRPM6 | c.5717C>T p.A1906V | Missense Mutation (SNP) | VAF 166/976 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV62519841; called by muse, mutect2, varscan2
- TTC28 | c.4771G>A p.D1591N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as rs1055884708; called by muse, mutect2, varscan2
- TYMP | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as rs776356925; called by muse, mutect2, varscan2
- USH2A | c.3304C>A p.Q1102K | Missense Mutation (SNP) | VAF 63/522 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56450221; called by muse, mutect2, varscan2
- VEGFC | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 148/396 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs755693482, COSV54606405; called by muse, mutect2, varscan2
- ZC3H12B | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV59051734; called by muse, mutect2, varscan2
- ZMAT1 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 210/314 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as rs757258463; called by muse, mutect2, varscan2
- ZNF347 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61968243; called by muse, mutect2, varscan2
- ZNF526 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 147/836 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs757513094; called by muse, mutect2, varscan2
- ZNF569 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV57594453; called by muse, mutect2, varscan2
- ZNF878 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV72156124; called by muse, mutect2, varscan2
- ACTN4 | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTR1B | c.863T>A p.M288K | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- ADAM8 | c.309_310del p.D103Efs*42 | Frame Shift Del (DEL) | VAF 18/109 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTS14 | c.2510G>A p.G837E | Missense Mutation (SNP) | VAF 78/217 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ADAMTS19 | c.2176+1G>T p.X726_splice | Splice Site (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- ADRA2B | c.1304G>T p.R435L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- AFF2 | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 140/203 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AKAP7 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALDH3B2 | c.426C>A p.C142* | Nonsense Mutation (SNP) | VAF 39/175 reads (22%) | called by muse, mutect2, varscan2
- ALK | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 121/700 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANAPC7 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 167/472 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ANK3 | c.10364C>A p.A3455D | Missense Mutation (SNP) | VAF 151/486 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2150G>T p.R717L | Missense Mutation (SNP) | VAF 105/211 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD24 | c.3116A>C p.Q1039P | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ANKRD26 | c.1636G>T p.V546F | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, varscan2
- APOBEC3B | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 63/588 reads (11%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- ARHGEF10 | c.3472+6G>T | Splice Region (SNP) | VAF 99/302 reads (33%) | called by mutect2, varscan2
- ARHGEF11 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATP6V0A4 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 266/1030 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ATP8A1 | c.3262G>C p.E1088Q | Missense Mutation (SNP) | VAF 165/408 reads (40%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- B4GALNT4 | c.2061C>G p.S687R | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- BBX | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- BTBD17 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C17orf50 | c.108C>G p.D36E | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CACNA1H | c.2498C>A p.T833N | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAD | c.3524C>T p.T1175I | Missense Mutation (SNP) | VAF 268/734 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CBLL2 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCER1 | c.761T>G p.V254G | Missense Mutation (SNP) | VAF 74/482 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- CCT8L2 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CEMIP2 | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 197/567 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFH | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 70/364 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFH | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 72/365 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHGB | c.359_360del p.T120Rfs*16 | Frame Shift Del (DEL) | VAF 24/142 reads (17%) | called by pindel, varscan2
- CIP2A | c.926T>G p.V309G | Missense Mutation (SNP) | VAF 160/516 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CNR1 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTLN | c.130del p.A44Qfs*46 | Frame Shift Del (DEL) | VAF 33/83 reads (40%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 123/407 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- COL11A1 | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 171/452 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COL28A1 | c.2837A>T p.H946L | Missense Mutation (SNP) | VAF 138/364 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CR1 | c.3548T>A p.L1183Q | Missense Mutation (SNP) | VAF 199/727 reads (27%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CREB5 | c.1114G>C p.E372Q (on ENST00000357727 / NM_182898.4; = p.E365Q on NM_004904.3) | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CREBBP | c.4522G>T p.D1508Y | Missense Mutation (SNP) | VAF 319/827 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CRYBG3 | c.6526C>T p.P2176S | Missense Mutation (SNP) | VAF 164/456 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CSNK2A3 | c.751A>T p.T251S | Missense Mutation (SNP) | VAF 206/490 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- DACH2 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 193/287 reads (67%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- DCC | c.1325G>T p.S442I | Missense Mutation (SNP) | VAF 239/729 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DENND1A | c.1517dup p.R507Efs*19 | Frame Shift Ins (INS) | VAF 40/360 reads (11%) | called by pindel, varscan2
- DGKB | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 127/619 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLGAP2 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- DMD | c.1423del p.E475Rfs*12 | Frame Shift Del (DEL) | VAF 171/336 reads (51%) | called by mutect2, pindel, varscan2
- DOCK4 | c.3211C>A p.L1071I | Missense Mutation (SNP) | VAF 132/452 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- DPEP1 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, varscan2
- DPP6 | c.1956C>A p.S652R (on ENST00000377770 / NM_001364500.2; = p.S590R on NM_001936.5) | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DPP6 | c.1957C>A p.H653N (on ENST00000377770 / NM_001364500.2; = p.H591N on NM_001936.5) | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- DSCAM | c.629G>A p.S210N | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EFCAB5 | c.1082T>A p.M361K | Missense Mutation (SNP) | VAF 130/368 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ELAVL2 | c.714-2A>T p.X238_splice | Splice Site (SNP) | VAF 37/205 reads (18%) | called by muse, mutect2, varscan2
- ENPP6 | c.185A>T p.Y62F | Missense Mutation (SNP) | VAF 189/405 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- EYS | c.6911G>T p.G2304V | Missense Mutation (SNP) | VAF 224/665 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- FAM47C | c.1427C>A p.P476Q | Missense Mutation (SNP) | VAF 148/215 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- FAM9B | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FBXO21 | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, varscan2
- FCRL5 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FETUB | c.942T>G p.N314K | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.036); called by muse, mutect2
- FIGNL1 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 112/312 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMO3 | c.1178T>C p.I393T | Missense Mutation (SNP) | VAF 122/441 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- FUT9 | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GALNT13 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALNT15 | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 250/578 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- GALNT7 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 105/290 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.194); called by muse, varscan2
- GAPVD1 | c.3257C>T p.S1086F (on ENST00000394104; = p.S1095F on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- GAREM2 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- GDPD5 | c.189G>T p.W63C | Missense Mutation (SNP) | VAF 70/456 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- GFRA1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GPR132 | c.1021A>T p.S341C | Missense Mutation (SNP) | VAF 109/208 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- GPR63 | c.991A>T p.T331S | Missense Mutation (SNP) | VAF 234/693 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- GPR75 | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 142/442 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); called by muse, varscan2
- GPX5 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, varscan2
- GSDMD | c.410+5G>A | Splice Region (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- HBS1L | c.2044A>G p.I682V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- HFM1 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HIVEP2 | c.6775G>A p.G2259S | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HSPA1L | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 172/435 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- HTR7 | c.1204del p.Q402Sfs*18 | Frame Shift Del (DEL) | VAF 35/251 reads (14%) | called by mutect2, pindel, varscan2
- HYDIN | c.4870G>T p.V1624L | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- IARS1 | c.2905del p.A969Lfs*5 | Frame Shift Del (DEL) | VAF 132/443 reads (30%) | called by mutect2, pindel, varscan2
- ICE1 | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 122/390 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ICE1 | c.3192dup p.G1065Wfs*25 | Frame Shift Ins (INS) | VAF 65/376 reads (17%) | called by mutect2, pindel, varscan2
- IGKV1-9 | c.95del p.F32Sfs*6 | Frame Shift Del (DEL) | VAF 111/721 reads (15%) | called by mutect2, pindel, varscan2
- IL12RB2 | c.1345T>G p.S449A | Missense Mutation (SNP) | VAF 219/562 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRX4 | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KANK1 | c.2517dup p.L840Tfs*4 | Frame Shift Ins (INS) | VAF 40/118 reads (34%) | called by mutect2, pindel, varscan2
- KANK3 | c.1538dup p.S514Ifs*18 | Frame Shift Ins (INS) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- KCNH8 | c.1944T>A p.F648L | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KDM2B | c.2962C>G p.P988A | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIAA1109 | c.4948A>G p.T1650A | Missense Mutation (SNP) | VAF 115/278 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIAA1614 | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KIF1A | c.3781C>A p.L1261M (on ENST00000320389 / NM_001379639.1; = p.L1253M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR2DS4 | c.613C>G p.R205G | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- KRT4 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 192/523 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KRTAP20-2 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 62/325 reads (19%) | PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LCT | c.3695T>C p.M1232T | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- LDB2 | c.409-2A>T p.X137_splice | Splice Site (SNP) | VAF 69/188 reads (37%) | called by muse, mutect2
- LMTK3 | c.4223G>T p.G1408V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.829); called by muse, varscan2
- LRCH1 | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 91/218 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRIG3 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 57/207 reads (28%) | called by muse, mutect2, varscan2
- LRP1B | c.12532del p.D4178Ifs*2 | Frame Shift Del (DEL) | VAF 57/327 reads (17%) | called by mutect2, pindel, varscan2
- LRP1B | c.8810G>C p.G2937A | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRP1B | c.3079G>T p.G1027C | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP2 | c.1076A>T p.D359V | Missense Mutation (SNP) | VAF 123/759 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- LRRTM4 | c.1313T>C p.M438T | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MAB21L3 | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- MAGEA8 | c.15G>C p.Q5H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MAGEB5 | c.401T>A p.M134K | Missense Mutation (SNP) | VAF 222/266 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEC1 | c.1339G>T p.V447L | Missense Mutation (SNP) | VAF 231/422 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, varscan2
- MAP2 | c.3935C>A p.A1312E | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBD3 | c.339_340insCAGATT p.T113_K114insQI | In Frame Ins (INS) | VAF 31/402 reads (8%) | called by muse*, mutect2
- MDN1 | c.6548G>T p.R2183L | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MINK1 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 87/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- MRC2 | c.4035C>A p.D1345E | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- MREG | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH2B | c.3682G>T p.G1228W | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- MST1R | c.3932A>G p.Y1311C | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MUC12 | c.2862del p.G955Afs*274 (on ENST00000379442; = p.G812Afs*274 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 150/1242 reads (12%) | called by pindel, varscan2
- MUC19 | c.768A>T p.T256= | Splice Region (SNP) | VAF 69/473 reads (15%) | called by muse, mutect2, varscan2
- MUC4 | c.72T>A p.H24Q | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- MYMK | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MYO3A | c.1906G>C p.A636P | Missense Mutation (SNP) | VAF 202/532 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIBAN1 | c.2141A>G p.K714R | Missense Mutation (SNP) | VAF 126/426 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- NKRF | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NLRP2 | c.1099T>A p.Y367N | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRG1 | c.804-1G>T p.X268_splice (on ENST00000405005 / NM_013964.5; = p.X273_splice on NM_013956.5) | Splice Site (SNP) | VAF 38/221 reads (17%) | called by muse, mutect2, varscan2
- NTN4 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 52/350 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NXPH1 | c.686G>C p.W229S | Missense Mutation (SNP) | VAF 130/519 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGDH | c.1524C>A p.Y508* | Nonsense Mutation (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- ONECUT3 | c.467del p.P156Rfs*9 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- OOSP2 | c.96G>C p.M32I | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- OR10V1 | c.508T>A p.C170S | Missense Mutation (SNP) | VAF 150/464 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- OR2M3 | c.284C>A p.A95D | Missense Mutation (SNP) | VAF 122/582 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- OR2M3 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 214/765 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR2T35 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 166/710 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OR4C16 | c.472A>T p.I158F | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OR4K2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 218/329 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR56B1 | c.281T>A p.F94Y | Missense Mutation (SNP) | VAF 121/255 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- OR5AP2 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2
- OR5H1 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 86/551 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OR5H2 | c.306C>A p.C102* | Nonsense Mutation (SNP) | VAF 96/341 reads (28%) | called by muse, mutect2, varscan2
- OR5H2 | c.307A>C p.M103L | Missense Mutation (SNP) | VAF 95/341 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5L1 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 95/585 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- OR5M11 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.028); called by muse, varscan2
- OR5V1 | c.447G>C p.W149C | Missense Mutation (SNP) | VAF 94/198 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSER1 | c.513A>T p.Q171H | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PADI4 | c.506A>T p.D169V | Missense Mutation (SNP) | VAF 118/257 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PCDH10 | c.1850C>A p.T617N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PCNT | c.6943A>G p.I2315V | Missense Mutation (SNP) | VAF 159/414 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PDCD1LG2 | c.565A>C p.N189H | Missense Mutation (SNP) | VAF 113/250 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PDE3B | c.1109C>A p.P370Q | Missense Mutation (SNP) | VAF 162/412 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PDE4DIP | c.4252G>T p.G1418W | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF3 | c.5786A>C p.H1929P | Missense Mutation (SNP) | VAF 68/459 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PLCXD3 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 163/470 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PLEKHA5 | c.1615C>T p.H539Y | Missense Mutation (SNP) | VAF 285/874 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PLEKHG7 | c.946A>G p.M316V | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PLPP7 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLPPR2 | c.928A>G p.M310V | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNA4 | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 93/385 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PLXNA4 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 103/352 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXND1 | c.2165G>A p.W722* | Nonsense Mutation (SNP) | VAF 74/229 reads (32%) | called by muse, mutect2, varscan2
- PNLIPRP2 | c.432_433del p.A145Gfs*18 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | called by pindel, varscan2
- PNLIPRP2 | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- POM121L12 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- POMGNT2 | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POU3F3 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POU6F1 | c.1540G>C p.V514L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.183); called by muse, mutect2
- PPFIA2 | c.2939T>A p.V980D | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PPP1R9A | c.773G>A p.W258* | Nonsense Mutation (SNP) | VAF 105/408 reads (26%) | called by muse, mutect2, varscan2
- PSD2 | c.1109A>T p.K370M | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- PSME4 | c.2714G>A p.G905E | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- PTPRC | c.2362A>T p.R788* | Nonsense Mutation (SNP) | VAF 214/794 reads (27%) | called by muse, mutect2, varscan2
- PTPRM | c.288C>A p.C96* | Nonsense Mutation (SNP) | VAF 136/457 reads (30%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 126/572 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PYHIN1 | c.674T>G p.V225G | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RALYL | c.358T>C p.S120P | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- RIMS2 | c.4738T>C p.S1580P (on ENST00000666250 / NM_001348490.2; = p.S1151P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF103 | c.1981G>A p.V661I | Missense Mutation (SNP) | VAF 68/434 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RNF213 | c.4723G>T p.E1575* | Nonsense Mutation (SNP) | VAF 68/183 reads (37%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1088G>T p.C363F (on ENST00000265814 / NM_001198628.1; = p.C336F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/294 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR2 | c.10574G>C p.R3525T | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SCN7A | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.355); called by muse, varscan2
- SF3B1 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SHC4 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SHCBP1 | c.1354C>A p.R452S | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SKP2 | c.1097A>G p.Q366R | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC35F3 | c.1085T>A p.I362N (on ENST00000366617 / NM_001300845.1; = p.I431N on NM_173508.4) | Missense Mutation (SNP) | VAF 159/535 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SMC4 | c.2418G>C p.K806N | Missense Mutation (SNP) | VAF 126/441 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SNTB2 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 101/628 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SORCS1 | c.1348C>A p.L450M | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SOST | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SPTLC3 | c.1545G>T p.T515= | Splice Region (SNP) | VAF 31/157 reads (20%) | called by muse, mutect2, varscan2
- SSU72P8 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- STXBP3 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- SYCP1 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SYT1 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 96/265 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TANGO6 | c.3176A>C p.D1059A | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.334); called by muse, mutect2
- TDRD6 | c.2687T>C p.F896S | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- TECPR1 | c.2857A>G p.I953V | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX47 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TLR4 | c.2325G>T p.E775D (on ENST00000355622 / NM_138554.5; = p.E735D on NM_003266.4) | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TMEM132D | c.744T>A p.N248K | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TMEM156 | c.823+2T>C p.X275_splice | Splice Site (SNP) | VAF 99/217 reads (46%) | called by muse, mutect2, varscan2
- TMEM52B | c.235G>T p.G79W (on ENST00000381923 / NM_001079815.1; = p.G59W on NM_153022.4) | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- TMTC2 | c.866C>G p.T289S | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- TRGV9 | c.91del p.S31Vfs*18 | Frame Shift Del (DEL) | VAF 72/316 reads (23%) | called by mutect2, pindel, varscan2
- TRPC6 | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 204/477 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC28 | c.1098del p.M367Wfs*15 | Frame Shift Del (DEL) | VAF 89/304 reads (29%) | called by mutect2, pindel, varscan2
- TTN | c.31496T>C p.I10499T (on ENST00000591111; = p.I9572T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/315 reads (17%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UBN1 | c.293G>T p.R98M | Missense Mutation (SNP) | VAF 60/370 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- UGT3A1 | c.1247C>A p.T416K | Missense Mutation (SNP) | VAF 80/520 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UNC13D | c.2535G>C p.R845S | Missense Mutation (SNP) | VAF 70/425 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- UPRT | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 94/163 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- URGCP | c.344C>T p.P115L (on ENST00000453200 / NM_001077663.3; = p.P106L on NM_017920.4) | Missense Mutation (SNP) | VAF 133/465 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- USP17L1 | c.1242C>G p.C414W | Missense Mutation (SNP) | VAF 65/416 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- USP31 | c.3074G>C p.R1025T | Missense Mutation (SNP) | VAF 52/419 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- VLDLR | c.2587-4A>G | Splice Region (SNP) | VAF 269/565 reads (48%) | called by muse, mutect2, varscan2
- VWC2 | c.889T>G p.C297G | Missense Mutation (SNP) | VAF 130/511 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- WAPL | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASHC4 | c.2882G>T p.G961V | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- WDFY4 | c.7392C>A p.S2464R | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- WDR87 | c.59C>G p.T20S | Missense Mutation (SNP) | VAF 25/312 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.205); called by muse, mutect2
- XAGE5 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 128/218 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, varscan2
- YY1AP1 | c.1397G>A p.S466N (on ENST00000295566 / NM_139118.2; = p.S409N on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZBED1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZFHX3 | c.1688G>T p.G563V | Missense Mutation (SNP) | VAF 83/505 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ZFHX4 | c.5421G>T p.Q1807H | Missense Mutation (SNP) | VAF 99/307 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ZFHX4 | c.9614A>T p.E3205V | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ZFP42 | c.616A>G p.R206G | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ZNF101 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF138 | c.739G>T p.G247* (on ENST00000307355 / NM_001367572.1; = p.G221* on NM_006524.4) | Nonsense Mutation (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- ZNF142 | c.2716T>C p.S906P (on ENST00000411696 / NM_001379660.1; = p.S706P on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF184 | c.2111G>C p.R704T | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- ZNF292 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF317 | c.353A>T p.E118V | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ZNF331 | c.509G>C p.W170S | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ZNF496 | c.705G>T p.W235C | Missense Mutation (SNP) | VAF 96/411 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF506 | c.569C>A p.T190K | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF521 | c.1891A>T p.T631S | Missense Mutation (SNP) | VAF 139/483 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF658 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 183/615 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ZNF699 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF729 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- ZNF737 | c.460A>T p.I154F | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF778 | c.1380_1384del p.S461Kfs*4 | Frame Shift Del (DEL) | VAF 51/239 reads (21%) | called by mutect2, pindel, varscan2
- ABCA2 | c.7386G>T p.T2462= (on ENST00000614293; = p.T2432= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- ACHE | c.582G>T p.G194= | Silent (SNP) | VAF 79/225 reads (35%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.3513G>T p.L1171= | Silent (SNP) | VAF 75/169 reads (44%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.4917G>T p.V1639= | Silent (SNP) | VAF 100/327 reads (31%) | catalogued as COSV101239081; called by muse, mutect2, varscan2
- ADGRA2 | c.3141G>T p.R1047= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1446478875; called by muse, mutect2, varscan2
- ADGRG5 | c.1248C>G p.V416= | Silent (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2
- AKAP12 | c.3762T>A p.T1254= | Silent (SNP) | VAF 109/336 reads (32%) | catalogued as COSV53571085; called by muse, mutect2, varscan2
- ALX1 | c.327G>A p.G109= | Silent (SNP) | VAF 189/481 reads (39%) | called by muse, mutect2, varscan2
- AMPH | c.933G>T p.P311= | Silent (SNP) | VAF 121/547 reads (22%) | catalogued as COSV57758411; called by muse, mutect2, varscan2
- ANKRD63 | c.684C>G p.G228= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- APOA5 | c.117C>T p.G39= | Silent (SNP) | VAF 179/427 reads (42%) | called by muse, mutect2, varscan2
- ASXL2 | c.366C>T p.S122= | Silent (SNP) | VAF 79/601 reads (13%) | called by muse, mutect2, varscan2
- AUTS2 | c.2457G>T p.A819= | Silent (SNP) | VAF 108/294 reads (37%) | catalogued as rs1309064482, COSV100716253; called by muse, mutect2, varscan2
- BMP4 | c.1197G>A p.E399= | Silent (SNP) | VAF 164/323 reads (51%) | called by muse, mutect2, varscan2
- BRINP3 | c.2115G>A p.E705= | Silent (SNP) | VAF 113/387 reads (29%) | catalogued as COSV66530810; called by muse, mutect2, varscan2
- C16orf96 | c.2937C>G p.G979= | Silent (SNP) | VAF 37/262 reads (14%) | called by muse, mutect2, varscan2
- CAMKMT | c.771G>A p.A257= | Silent (SNP) | VAF 200/629 reads (32%) | catalogued as rs201420188, COSV65926498; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC96 | c.1203G>A p.Q401= | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as rs1243185654; called by muse, mutect2, varscan2
- CDC73 | c.24G>C p.L8= | Silent (SNP) | VAF 64/218 reads (29%) | called by muse, mutect2, varscan2
- CEACAM20 | c.1209C>T p.I403= | Silent (SNP) | VAF 213/418 reads (51%) | called by muse, mutect2, varscan2
- CNR1 | c.330C>A p.V110= | Silent (SNP) | VAF 51/298 reads (17%) | called by muse, mutect2, varscan2
- CRAMP1 | c.3195C>T p.T1065= | Silent (SNP) | VAF 112/470 reads (24%) | catalogued as rs1175049312; called by muse, mutect2, varscan2
- CRLF2 | c.414T>C p.C138= | Silent (SNP) | VAF 100/398 reads (25%) | called by muse, mutect2, varscan2
- CSMD2 | c.2220C>G p.V740= | Silent (SNP) | VAF 219/381 reads (57%) | called by muse, mutect2, varscan2
- DACH2 | c.1266A>T p.I422= | Silent (SNP) | VAF 93/154 reads (60%) | called by muse, mutect2, varscan2
- DOCK1 | c.2334C>A p.S778= | Silent (SNP) | VAF 59/430 reads (14%) | called by muse, mutect2, varscan2
- DPYSL2 | c.1059G>A p.E353= | Silent (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2, varscan2
- DYSF | c.3009C>G p.L1003= | Silent (SNP) | VAF 78/478 reads (16%) | called by muse, mutect2, varscan2
- E2F7 | c.942A>T p.I314= | Silent (SNP) | VAF 85/499 reads (17%) | called by muse, mutect2, varscan2
- EPB41L3 | c.159G>C p.A53= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV59445783; called by muse, mutect2, varscan2
- EPS8L1 | c.225G>A p.E75= | Silent (SNP) | VAF 42/284 reads (15%) | called by muse, mutect2, varscan2
- FAHD2A | c.378G>T p.V126= | Silent (SNP) | VAF 36/342 reads (11%) | called by muse, mutect2, varscan2
- FAM102A | c.279C>T p.G93= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as rs200068877; called by muse, mutect2, varscan2
- FAM110B | c.615G>A p.K205= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- FBLN1 | c.666G>C p.T222= | Silent (SNP) | VAF 169/497 reads (34%) | called by muse, mutect2, varscan2
- GABRG2 | c.387C>T p.N129= | Silent (SNP) | VAF 117/507 reads (23%) | catalogued as COSV62720019; called by muse, mutect2, varscan2
- GAD2 | c.1227T>A p.V409= | Silent (SNP) | VAF 68/318 reads (21%) | called by muse, mutect2, varscan2
- GCC2 | c.2811T>G p.S937= | Silent (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2
- GGTLC1 | c.210G>T p.G70= | Silent (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- GLI3 | c.2754G>T p.L918= | Silent (SNP) | VAF 33/250 reads (13%) | catalogued as rs766051683, COSV101229815; called by muse, mutect2, varscan2
- GLRX2 | c.384T>C p.G128= (on ENST00000367439 / NM_197962.3; = p.G129= on NM_016066.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2
- GP2 | c.724T>C p.L242= (on ENST00000381362 / NM_001007240.3; = p.L239= on NM_001502.4) | Silent (SNP) | VAF 50/394 reads (13%) | called by muse, mutect2
- HEPACAM2 | c.837C>G p.T279= (on ENST00000394468 / NM_001039372.4; = p.T267= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 115/457 reads (25%) | called by muse, mutect2, varscan2
- HNRNPU | c.1125A>G p.E375= (on ENST00000283179; = p.E437= on NM_004501.3) | Silent (SNP) | VAF 253/838 reads (30%) | called by muse, mutect2, varscan2
- IGFBP1 | c.228A>G p.A76= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- IGLON5 | c.681C>A p.R227= | Silent (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- IMMP2L | c.513G>A p.Q171= | Silent (SNP) | VAF 157/648 reads (24%) | called by muse, mutect2, varscan2
- KCNAB1 | c.138C>T p.S46= | Silent (SNP) | VAF 158/985 reads (16%) | catalogued as rs564315619; called by muse, mutect2, varscan2
- KLRD1 | c.462G>T p.A154= | Silent (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- KMT2D | c.16392G>A p.T5464= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as rs757610867; called by muse, mutect2, varscan2
- LRFN3 | c.1836C>T p.V612= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- LRRC31 | c.210C>T p.S70= | Silent (SNP) | VAF 103/484 reads (21%) | catalogued as rs754387888; called by muse, mutect2, varscan2
- MAGEB1 | c.1032C>T p.S344= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV66776284; called by muse, varscan2
- MIA3 | c.1548A>T p.T516= | Silent (SNP) | VAF 176/608 reads (29%) | called by muse, mutect2, varscan2
- MMP25 | c.54C>T p.P18= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs762957606; called by muse, mutect2, varscan2
- MYLK3 | c.2061G>A p.E687= | Silent (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- MYPN | c.687A>G p.E229= | Silent (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- NAALADL2 | c.690T>A p.T230= | Silent (SNP) | VAF 127/1403 reads (9%) | catalogued as rs1275879209; called by muse, mutect2
- NAALADL2 | c.1242A>G p.R414= | Silent (SNP) | VAF 55/338 reads (16%) | called by muse, mutect2, varscan2
- NAV3 | c.1593C>T p.G531= | Silent (SNP) | VAF 113/406 reads (28%) | catalogued as rs766198467; called by muse, mutect2, varscan2
- NEB | c.14925C>T p.D4975= | Silent (SNP) | VAF 120/384 reads (31%) | catalogued as rs896168076; called by muse, mutect2, varscan2
- NIPBL | c.8391C>T p.A2797= | Silent (SNP) | VAF 112/389 reads (29%) | catalogued as rs997526101, COSV99239550; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOL4 | c.301C>A p.R101= | Silent (SNP) | VAF 78/375 reads (21%) | catalogued as COSV52347295; called by muse, mutect2, varscan2
- NPAP1 | c.1185C>G p.T395= | Silent (SNP) | VAF 123/379 reads (32%) | catalogued as COSV100274879; called by muse, mutect2, varscan2
- NUF2 | c.705A>G p.E235= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1340138220; called by muse, mutect2
- OR10G2 | c.699A>T p.I233= | Silent (SNP) | VAF 141/214 reads (66%) | called by muse, mutect2
- OR11H1 | c.432C>G p.L144= | Silent (SNP) | VAF 106/336 reads (32%) | catalogued as rs1235632803, COSV99422034; called by mutect2, varscan2
- OR14A2 | c.675G>A p.K225= | Silent (SNP) | VAF 110/328 reads (34%) | called by muse, mutect2, varscan2
- OR2T3 | c.909C>A p.T303= | Silent (SNP) | VAF 158/991 reads (16%) | called by muse, mutect2, varscan2
- OR5D14 | c.597G>T p.L199= | Silent (SNP) | VAF 171/457 reads (37%) | called by muse, mutect2, varscan2
- OR5D18 | c.846G>A p.V282= | Silent (SNP) | VAF 62/354 reads (18%) | catalogued as rs1006714566; called by muse, mutect2, varscan2
- PARP9 | c.1557G>A p.L519= | Silent (SNP) | VAF 78/398 reads (20%) | catalogued as rs773484894; called by muse, mutect2, varscan2
- PCDHA11 | c.999T>C p.C333= | Silent (SNP) | VAF 123/310 reads (40%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.1752C>G p.P584= | Silent (SNP) | VAF 73/191 reads (38%) | catalogued as rs540850539; called by muse, varscan2
- PCDHGA7 | c.2214G>T p.S738= | Silent (SNP) | VAF 78/195 reads (40%) | catalogued as rs541716228, COSV53997825, COSV99535093; called by muse, mutect2, varscan2
- PGAM4 | c.150T>C p.Y50= | Silent (SNP) | VAF 110/201 reads (55%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3993A>G p.V1331= (on ENST00000676171; = p.V1290= on NM_004570.5) | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as rs1209020966; called by muse, mutect2, varscan2
- POM121L12 | c.163C>T p.L55= | Silent (SNP) | VAF 67/223 reads (30%) | catalogued as rs1186143341, COSV68692448; called by muse, mutect2, varscan2
- POTEC | c.1020G>T p.T340= | Silent (SNP) | VAF 95/400 reads (24%) | catalogued as COSV62803029; called by muse, mutect2, varscan2
- PSMA8 | c.507A>C p.I169= | Silent (SNP) | VAF 99/253 reads (39%) | called by muse, mutect2, varscan2
- RAP1GAP | c.549C>A p.T183= | Silent (SNP) | VAF 102/252 reads (40%) | called by muse, mutect2, varscan2
- RBM19 | c.906G>T p.P302= | Silent (SNP) | VAF 137/432 reads (32%) | catalogued as COSV99926117; called by muse, mutect2, varscan2
- RBMX | c.42G>C p.G14= | Silent (SNP) | VAF 42/350 reads (12%) | called by muse, mutect2, varscan2
- RGL1 | c.639C>T p.S213= (on ENST00000360851 / NM_001297672.2; = p.S248= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 128/428 reads (30%) | called by muse, mutect2, varscan2
- RRP12 | c.1977C>T p.V659= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs370174382; called by muse, mutect2, varscan2
- SAC3D1 | c.135G>T p.A45= | Silent (SNP) | VAF 32/84 reads (38%) | called by mutect2, varscan2
- SBNO2 | c.1665G>T p.R555= | Silent (SNP) | VAF 30/118 reads (25%) | called by muse, mutect2, varscan2
- SHOX | c.132G>T p.A44= | Silent (SNP) | VAF 60/251 reads (24%) | catalogued as COSV61862176; called by muse, mutect2, varscan2
- SLC17A6 | c.1089G>A p.V363= | Silent (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- SLC22A13 | c.993G>T p.R331= | Silent (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- SLC38A1 | c.528C>T p.A176= | Silent (SNP) | VAF 37/271 reads (14%) | called by muse, mutect2, varscan2
- SNTG1 | c.400C>T p.L134= | Silent (SNP) | VAF 31/254 reads (12%) | called by muse, mutect2, varscan2
- SOX11 | c.1263G>A p.L421= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs947760428; called by muse, mutect2, varscan2
- SRC | c.1086G>A p.R362= | Silent (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- STYXL2 | c.3045C>G p.G1015= | Silent (SNP) | VAF 78/327 reads (24%) | called by muse, mutect2, varscan2
- TAS2R38 | c.27T>A p.T9= | Silent (SNP) | VAF 56/172 reads (33%) | called by muse, varscan2
- TDRD6 | c.294G>C p.L98= | Silent (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- TECPR2 | c.3243C>T p.L1081= | Silent (SNP) | VAF 81/612 reads (13%) | catalogued as rs754697484; called by muse, mutect2, varscan2
- TENM1 | c.4734G>T p.A1578= | Silent (SNP) | VAF 74/135 reads (55%) | catalogued as COSV100950980, COSV64436887; called by muse, mutect2, varscan2
- TGM5 | c.1179C>T p.P393= (on ENST00000220420 / NM_201631.4; = p.P311= on NM_004245.4) | Silent (SNP) | VAF 252/631 reads (40%) | catalogued as COSV55010354, COSV99589163; called by muse, mutect2, varscan2
- TMPRSS11B | c.555T>A p.I185= | Silent (SNP) | VAF 93/202 reads (46%) | called by muse, mutect2, varscan2
- TOMM70 | c.903C>A p.A301= | Silent (SNP) | VAF 94/302 reads (31%) | called by muse, mutect2, varscan2
- TRIM77 | c.1182A>T p.P394= | Silent (SNP) | VAF 108/241 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.6177C>A p.I2059= (on ENST00000591111; = p.I2013= on NM_003319.4) | Silent (SNP) | VAF 179/919 reads (19%) | catalogued as COSV60278939, COSV60401714; called by muse, mutect2, varscan2
- UBC | c.675C>T p.L225= | Silent (SNP) | VAF 114/608 reads (19%) | catalogued as rs761248355; called by muse, mutect2, varscan2
- USH2A | c.1368C>A p.I456= | Silent (SNP) | VAF 136/524 reads (26%) | catalogued as COSV56384710; called by muse, mutect2, varscan2
- WDR27 | c.525C>T p.T175= | Silent (SNP) | VAF 75/552 reads (14%) | catalogued as COSV61218285; called by muse, mutect2, varscan2
- WDR7 | c.4197A>G p.A1399= | Silent (SNP) | VAF 143/555 reads (26%) | called by muse, mutect2, varscan2
- ZEB2 | c.1866C>T p.P622= | Silent (SNP) | VAF 72/481 reads (15%) | catalogued as COSV100356589; called by muse, mutect2, varscan2
- ZFHX4 | c.6802C>A p.R2268= | Silent (SNP) | VAF 65/540 reads (12%) | catalogued as COSV51490982; called by muse, varscan2
- AC004223.3 | c.-46C>T | 5'UTR (SNP) | VAF 16/319 reads (5%) | called by muse, mutect2
- AC068643.2 | n.593+313C>A | Intron (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2
- AC139792.3 | chr5:34124473 C>A | 5'Flank (SNP) | VAF 43/214 reads (20%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.1136A>T | RNA (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- ANKRD28 | c.28-18947del | Intron (DEL) | VAF 36/78 reads (46%) | called by mutect2, varscan2
- AP001993.1 | n.3383C>A | RNA (SNP) | VAF 114/322 reads (35%) | catalogued as rs1243815829; called by muse, mutect2, varscan2
- APLP1 | c.148-91G>C | Intron (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- ATP8B1 | c.1029+14A>T | Intron (SNP) | VAF 38/160 reads (24%) | called by muse, mutect2, varscan2
- BRSK1 | chr19:55282153 C>T | 5'Flank (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- CDK4 | c.632+162_632+163insT | Intron (INS) | VAF 21/62 reads (34%) | called by mutect2, pindel*, varscan2
- CHN1 | c.*421A>C | 3'UTR (SNP) | VAF 237/1376 reads (17%) | called by mutect2, varscan2
- CHN1 | c.*420C>A | 3'UTR (SNP) | VAF 236/1378 reads (17%) | called by mutect2, varscan2
- CLEC4A | c.299-813G>T | Intron (SNP) | VAF 22/100 reads (22%) | catalogued as rs1202045644; called by muse, mutect2, varscan2
- DLGAP1 | c.957+4433A>T | Intron (SNP) | VAF 27/131 reads (21%) | called by muse, mutect2, varscan2
- DMD | c.-11A>G | 5'UTR (SNP) | VAF 191/289 reads (66%) | called by muse, mutect2, varscan2
- DPP3 | c.1452+10G>T | Intron (SNP) | VAF 78/195 reads (40%) | called by muse, mutect2, varscan2
- ENPP3 | c.78+989G>T | Intron (SNP) | VAF 74/224 reads (33%) | called by muse, mutect2, varscan2
- ESAM | c.250-16T>C | Intron (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2, varscan2
- FAM161A | c.*326del | 3'UTR (DEL) | VAF 53/171 reads (31%) | catalogued as rs1171046817; called by mutect2, pindel, varscan2
- FRG1BP | n.337C>T | RNA (SNP) | VAF 57/335 reads (17%) | called by muse, mutect2, varscan2
- GLI1 | c.-22C>T | 5'UTR (SNP) | VAF 147/404 reads (36%) | called by muse, mutect2, varscan2
- GUSBP10 | n.251C>A | RNA (SNP) | VAF 80/314 reads (25%) | catalogued as rs766815205; called by muse, mutect2, varscan2
- HIP1R | chr12:122834993 G>C | 5'Flank (SNP) | VAF 77/512 reads (15%) | called by muse, mutect2, varscan2
- IRAK1 | c.137-26G>T | Intron (SNP) | VAF 15/19 reads (79%) | catalogued as rs782585254; called by muse, mutect2, varscan2
- KLHL1 | c.*57G>T | 3'UTR (SNP) | VAF 54/145 reads (37%) | called by muse, mutect2, varscan2
- KRT8P11 | n.782G>T | RNA (SNP) | VAF 75/234 reads (32%) | called by muse, mutect2, varscan2
- LILRB5 | c.1357+23del | Intron (DEL) | VAF 28/142 reads (20%) | called by mutect2, pindel, varscan2
- LIN7A | c.82+1856A>T | Intron (SNP) | VAF 44/442 reads (10%) | called by muse, mutect2
- LINC00632 | n.56C>T | RNA (SNP) | VAF 32/189 reads (17%) | catalogued as rs952785824; called by muse, mutect2, varscan2
- LINC00692 | n.582T>C | RNA (SNP) | VAF 64/137 reads (47%) | called by muse, mutect2, varscan2
- LINC02213 | n.70A>G | RNA (SNP) | VAF 66/469 reads (14%) | catalogued as rs980903097; called by muse, mutect2, varscan2
- LPCAT3 | c.151+16812C>T | Intron (SNP) | VAF 136/429 reads (32%) | called by muse, mutect2, varscan2
- MIR520C | n.64C>T | RNA (SNP) | VAF 76/303 reads (25%) | called by muse, mutect2, varscan2
- MTX2 | c.40+596G>T | Intron (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- NCBP1 | c.*1G>C | 3'UTR (SNP) | VAF 69/373 reads (18%) | catalogued as rs758076211; called by muse, mutect2, varscan2
- NEB | c.8890-473G>T | Intron (SNP) | VAF 143/352 reads (41%) | called by muse, mutect2, varscan2
- OR2W5 | n.367C>A | RNA (SNP) | VAF 83/254 reads (33%) | called by muse, mutect2, varscan2
- PAX4 | c.771+16G>T | Intron (SNP) | VAF 144/557 reads (26%) | called by muse, mutect2, varscan2
- PDE4DIP | c.637-7087A>G | Intron (SNP) | VAF 86/429 reads (20%) | catalogued as COSV100519778, COSV57703633; called by muse, mutect2, varscan2
- PI4KAP2 | n.2269G>A | RNA (SNP) | VAF 11/60 reads (18%) | catalogued as rs941099626; called by mutect2, varscan2
- PRSS40A | n.142-2129C>A | Intron (SNP) | VAF 22/114 reads (19%) | called by mutect2, varscan2
- RELN | c.10281-115T>C | Intron (SNP) | VAF 24/135 reads (18%) | catalogued as rs1314286965; called by muse, mutect2
- RGS10 | c.49+6095G>T | Intron (SNP) | VAF 16/107 reads (15%) | catalogued as COSV100962697; called by muse, mutect2, varscan2
- RPL36 | c.228+10C>T | Intron (SNP) | VAF 17/80 reads (21%) | catalogued as rs549613569; called by muse, mutect2, varscan2
- SBF2 | c.-7G>A | 5'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- SCUBE1 | c.*5378C>A | 3'UTR (SNP) | VAF 112/347 reads (32%) | called by muse, varscan2
- SHANK2 | c.1854-115T>G | Intron (SNP) | VAF 91/444 reads (20%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.3112C>G | RNA (SNP) | VAF 146/811 reads (18%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.920G>T | RNA (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- SYNE1 | c.2569-695G>T | Intron (SNP) | VAF 46/312 reads (15%) | called by muse, mutect2, varscan2
- TMEM179 | c.*36C>A | 3'UTR (SNP) | VAF 71/135 reads (53%) | called by muse, mutect2, varscan2
- TNFRSF13B | c.*17G>A | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2, varscan2
- TP73-AS1 | n.1660G>T | RNA (SNP) | VAF 81/167 reads (49%) | called by muse, mutect2, varscan2
- TTN | c.10361-5313G>A | Intron (SNP) | VAF 191/349 reads (55%) | catalogued as COSV60019311; called by muse, mutect2, varscan2
- UGT3A1 | c.843+2475C>T | Intron (SNP) | VAF 90/304 reads (30%) | catalogued as rs1036323532; called by muse, mutect2, varscan2
- UQCRB | c.*3603C>A | 3'UTR (SNP) | VAF 138/804 reads (17%) | catalogued as rs558455700; called by muse, mutect2, varscan2
- WASHC3 | c.-1G>C | 5'UTR (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- WDFY4 | c.*174T>C | 3'UTR (SNP) | VAF 53/257 reads (21%) | called by muse, mutect2, varscan2
- WDR11 | c.3438-47G>T | Intron (SNP) | VAF 188/494 reads (38%) | called by muse, mutect2, varscan2
- WDR17 | chr4:176181468 C>A | 3'Flank (SNP) | VAF 20/60 reads (33%) | called by muse, varscan2
- ZEB2 | c.73+4555del | Intron (DEL) | VAF 296/1012 reads (29%) | catalogued as rs1210498099; called by mutect2, pindel, varscan2
- ZFYVE26 | c.*9A>G | 3'UTR (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- ZNF493 | c.-31G>A | 5'UTR (SNP) | VAF 34/109 reads (31%) | catalogued as COSV62752637; called by muse, mutect2, varscan2
- ZNF587 | c.34-32del | Intron (DEL) | VAF 22/128 reads (17%) | called by mutect2, varscan2
